Somatic mutation profile of tumor specimen 0DYM2A from CCDI case PBCSKL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 7.2 years (2,643 days).
Specimen 0DYM2A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09aae34b-9d5d-45c8-adf4-e248fc3a63a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYM1F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f85ab440-4075-4401-b7ac-01424494a65f

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 2, Intron 2, 3'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 458/888 reads (52%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 109/846 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 619/697 reads (89%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CARD6 | c.2545A>G p.I849V | Missense Mutation (SNP) | VAF 189/693 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766077676; called by muse, mutect2, varscan2
- FAM171A1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 196/779 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374230936; called by muse, mutect2, varscan2
- HLTF | c.2692C>A p.Q898K | Missense Mutation (SNP) | VAF 12/1652 reads (1%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs1313494832; called by muse*, mutect2
- SHISAL1 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 485/1115 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); catalogued as rs772942802; called by muse, mutect2, varscan2
- UNC13C | c.4247A>C p.E1416A | Missense Mutation (SNP) | VAF 141/189 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1470382704; called by muse, mutect2, varscan2
- AGFG1 | c.1391G>A p.G464D | Missense Mutation (SNP) | VAF 41/1164 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AGTPBP1 | c.580G>C p.V194L | Missense Mutation (SNP) | VAF 803/1155 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 60/1631 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- DIAPH2 | c.655A>C p.K219Q | Missense Mutation (SNP) | VAF 331/742 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KRT72 | c.642G>C p.R214S | Missense Mutation (SNP) | VAF 166/781 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OXR1 | c.889G>A p.D297N (on ENST00000442977 / NM_001198532.1; = p.D296N on NM_018002.3) | Missense Mutation (SNP) | VAF 371/888 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PCDHGA6 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 70/1096 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2
- SOX3 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 125/624 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PRDM8 | c.1989G>A p.E663= | Silent (SNP) | VAF 167/898 reads (19%) | catalogued as rs1251893424; called by muse, mutect2, varscan2
- UMODL1 | c.144G>A p.V48= | Silent (SNP) | VAF 226/1229 reads (18%) | catalogued as rs745635550; called by muse, mutect2, varscan2
- ATG4A | c.815-69C>T | Intron (SNP) | VAF 186/350 reads (53%) | called by muse, mutect2
- FANCC | c.1329+310_1329+330del | Intron (DEL) | VAF 446/648 reads (69%) | called by mutect2, pindel, varscan2
- NSDHL | c.*7C>G | 3'UTR (SNP) | VAF 30/636 reads (5%) | catalogued as rs1556848564; called by muse, mutect2
- STX5 | c.*6C>G | 3'UTR (SNP) | VAF 134/589 reads (23%) | called by muse, mutect2, varscan2
